Gene-level copy-number profile of tumor specimen ALCH-ADUW-TTP1-A from ALCHEMIST case ALCH-ADUW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,216 days).
Specimen ALCH-ADUW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file af586714-e5c4-4e5a-8519-46c987804a6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/abee9b76-1b1a-43ec-8f0c-07da2cc2f7ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 28; copy number 2: 6,364; copy number 3: 592; copy number 4: 34,132; copy number 5: 464; copy number 6: 12,627; copy number 7: 1,411; copy number 8: 2,721; copy number 9: 7; copy number 10: 47; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:22,219,703–22,232,101, 1 gene: PHYHIP.
- chr15:65,285,461–65,285,591, 1 gene (within-gene range 0–1): SNORA24B.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 56 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:230,592,660–230,696,888, 4 genes, copy number 9: LINC01737, AL158214.1, COG2, AL158214.2.
- chr9:137,554,444–137,590,512, 2 genes, copy number 11: DPH7, ZMYND19.
- chr14:102,592,649–102,730,561, 3 genes, copy number 9 (within-gene range 9–10): RCOR1, RPL23AP11, Y_RNA.
- chr22:50,089,879–50,801,309, 47 genes, copy number 10: MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
